Somatic mutation profile of tumor specimen TCGA-FB-AAPZ-01A (aliquot TCGA-FB-AAPZ-01A-11D-A40W-08) from TCGA case TCGA-FB-AAPZ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.3 years (19,847 days).
Specimen TCGA-FB-AAPZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7800451b-af90-4f11-a65b-ff0e85093e45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPZ-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPZ-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e41f84a6-d8ae-411e-b538-6a2440f35f4f

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1141814, CM950561, COSV100516282; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 91/265 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 131/192 reads (68%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM3 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 187/306 reads (61%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99184668; called by muse, mutect2, varscan2
- ADAMTS19 | c.3188G>A p.R1063H | Missense Mutation (SNP) | VAF 56/868 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs776454235, COSV50787375; called by muse, mutect2
- ATP10A | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.085); catalogued as rs780784865, COSV63519891; called by muse, mutect2
- BEGAIN | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV62068221; called by muse, mutect2, varscan2
- BRINP3 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs367715031, COSV66542693; called by muse, mutect2, varscan2
- CD8B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 124/360 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs772468080, COSV58928598; called by muse, varscan2
- CDIPT | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as COSV99570233; called by muse, mutect2, varscan2
- CLEC1B | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 115/2527 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs935242723, COSV53724634, COSV53725234; called by muse, mutect2
- CYBB | c.483+2T>C p.X161_splice | Splice Site (SNP) | VAF 28/217 reads (13%) | catalogued as CS961541, COSV101059783; called by muse, mutect2, varscan2
- ENPP4 | c.871A>C p.M291L | Missense Mutation (SNP) | VAF 154/497 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100320374; called by muse, mutect2, varscan2
- FEM1B | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 137/204 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV100183701; called by muse, mutect2, varscan2
- KANSL1L | c.2788T>A p.L930I | Missense Mutation (SNP) | VAF 107/553 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55990956, COSV99910682; called by muse, mutect2, varscan2
- MEF2C | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60928227, COSV60929247; called by muse, mutect2, varscan2
- MX2 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 349/828 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV100416017; called by muse, mutect2, varscan2
- NTF3 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 238/544 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV58417648; called by muse, mutect2, varscan2
- PHACTR3 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 478/1108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732793; called by muse, mutect2, varscan2
- PSG8 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 323/866 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs200167716, COSV100126217; called by muse, mutect2, varscan2
- RBM45 | c.1417C>G p.Q473E (on ENST00000616198 / NM_001365579.1; = p.Q471E on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.3); catalogued as COSV99617783; called by muse, mutect2, varscan2
- RNF165 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 85/147 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as rs373942142; called by muse, mutect2, varscan2
- ROCK1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296473; called by muse, mutect2, varscan2
- SEPTIN7 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1289333452, COSV63257458; called by muse, mutect2
- SYNE2 | c.19219G>A p.E6407K | Missense Mutation (SNP) | VAF 231/475 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100648008; called by muse, mutect2, varscan2
- TCF7L1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 164/681 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765101094, COSV56399755; called by muse, mutect2, varscan2
- TIGD2 | c.1548dup p.Q517Tfs*6 | Frame Shift Ins (INS) | VAF 76/423 reads (18%) | catalogued as rs758519530; called by mutect2, varscan2
- TMEM178A | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56143491, COSV99931955; called by muse, mutect2
- TNNI3 | c.541A>C p.T181P | Missense Mutation (SNP) | VAF 276/693 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99402908; called by muse, mutect2, varscan2
- TRAT1 | c.330C>A p.Y110* | Nonsense Mutation (SNP) | VAF 63/509 reads (12%) | catalogued as COSV55469240, COSV99849352; called by muse, mutect2, varscan2
- MYOM1 | c.4241_4250del p.L1414Rfs*14 | Frame Shift Del (DEL) | VAF 33/285 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.3117G>A p.L1039= | Silent (SNP) | VAF 163/464 reads (35%) | catalogued as COSV99273350; called by muse, mutect2, varscan2
- DSCAM | c.222C>T p.H74= | Silent (SNP) | VAF 53/430 reads (12%) | catalogued as rs371757548; called by muse, mutect2, varscan2
- EPHA8 | c.1953C>T p.Y651= | Silent (SNP) | VAF 52/205 reads (25%) | catalogued as rs1021905173, COSV99385156; called by muse, mutect2, varscan2
- FOXD4L5 | c.795G>A p.P265= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1378989071; called by mutect2, varscan2
- FOXD4L6 | c.795G>A p.P265= | Silent (SNP) | VAF 13/82 reads (16%) | called by mutect2, varscan2
- KCTD16 | c.1251T>C p.P417= | Silent (SNP) | VAF 188/552 reads (34%) | catalogued as COSV101568831, COSV72580485; called by muse, mutect2, varscan2
- NRXN3 | c.1302C>T p.G434= (on ENST00000335750 / NM_001330195.2; = p.G61= on NM_004796.6) | Silent (SNP) | VAF 222/445 reads (50%) | catalogued as rs765292135, COSV59710548, COSV59743312; called by muse, mutect2, varscan2
- OR4Q3 | c.153C>A p.L51= | Silent (SNP) | VAF 483/958 reads (50%) | catalogued as COSV100057161; called by muse, mutect2, varscan2
- PKD1L1 | c.2424C>T p.F808= | Silent (SNP) | VAF 61/156 reads (39%) | catalogued as rs764327755, COSV99220361; ClinVar: likely benign; called by muse, mutect2, varscan2
- PSG11 | c.537G>A p.L179= | Silent (SNP) | VAF 832/2070 reads (40%) | catalogued as COSV100105922; called by muse, mutect2, varscan2
- RHOA | c.66C>T p.L22= | Silent (SNP) | VAF 156/468 reads (33%) | catalogued as rs1559501739, COSV101371140; called by muse, mutect2, varscan2
- TAS1R2 | c.330G>A p.P110= | Silent (SNP) | VAF 32/488 reads (7%) | catalogued as rs370454471; called by muse, mutect2
- ZNF546 | c.1395T>C p.G465= | Silent (SNP) | VAF 225/566 reads (40%) | catalogued as COSV100713494; called by muse, mutect2, varscan2
